Somatic mutation profile of tumor specimen C3L-02403-01 (aliquot CPT0203150011) from CPTAC case C3L-02403, project CPTAC-3 (Uterus, NOS — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Uterus, NOS; AJCC pathologic stage: Stage I; FIGO stage: Stage I; Tumor grade: G2; Age at diagnosis: 78.1 years (28,516 days).
Specimen C3L-02403-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Uterus; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ab8919a4-4a08-4e75-8808-a56d3b1dc46c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-02403-71 (Blood Derived Normal), aliquot CPT0203210002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f6612877-ac01-4457-998a-91798d614759

The open-access MAF lists 71 somatic variants for this specimen: 48 protein-altering or splice-affecting, 13 silent, 10 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 37, Silent 13, Nonsense Mutation 5, Intron 5, In Frame Del 4, 5'Flank 2, 3'Flank 2, Frame Shift Ins 1, 3'UTR 1, In Frame Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PTEN | c.821G>A p.W274* | Nonsense Mutation (SNP) | VAF 152/179 reads (85%) | hotspot (GDC flag); catalogued as rs786204875, CM1010008, CM151667, COSV100909695, COSV64288869; called by muse, mutect2, varscan2
- ABR | c.2473C>T p.H825Y (on ENST00000302538 / NM_021962.5; = p.H788Y on NM_001092.5) | Missense Mutation (SNP) | VAF 93/202 reads (46%) | SIFT tolerated (0.95); PolyPhen benign (0.296); catalogued as rs1247135407; called by muse, varscan2
- ARHGEF11 | c.4235G>A p.R1412H | Missense Mutation (SNP) | VAF 91/368 reads (25%) | SIFT tolerated, low confidence (0.7); PolyPhen benign (0); catalogued as rs201607774, COSV59356227; called by muse, mutect2, varscan2
- BLNK | c.838C>G p.R280G | Missense Mutation (SNP) | VAF 183/431 reads (42%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV56408891; called by muse, mutect2, varscan2
- CREBBP | c.5484C>A p.Y1828* | Nonsense Mutation (SNP) | VAF 186/445 reads (42%) | catalogued as COSV52141265; called by muse, mutect2, varscan2
- EFEMP2 | c.403C>T p.R135C | Missense Mutation (SNP) | VAF 368/779 reads (47%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.761); catalogued as rs760668617; called by muse, mutect2, varscan2
- GMPS | c.1019T>C p.I340T | Missense Mutation (SNP) | VAF 23/46 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs898578201; called by muse, mutect2, varscan2
- HYI | c.320T>C p.V107A | Missense Mutation (SNP) | VAF 123/313 reads (39%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as rs746723799, COSV100981267; called by muse, mutect2, varscan2
- KDM6B | c.175C>T p.P59S | Missense Mutation (SNP) | VAF 17/482 reads (4%) | SIFT tolerated, low confidence (0.57); PolyPhen benign (0); catalogued as rs1214538742; called by muse, mutect2
- LRP2 | c.9574C>T p.R3192W | Missense Mutation (SNP) | VAF 64/134 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs761574622, COSV55547925; called by muse, mutect2, varscan2
- MAST3 | c.396C>A p.F132L | Missense Mutation (SNP) | VAF 154/355 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.836); catalogued as COSV53223545; called by muse, mutect2, varscan2
- NAA25 | c.961C>T p.R321* | Nonsense Mutation (SNP) | VAF 80/199 reads (40%) | catalogued as COSV55702111; called by muse, mutect2, varscan2
- NRDE2 | c.914C>T p.A305V | Missense Mutation (SNP) | VAF 95/235 reads (40%) | SIFT tolerated (0.12); PolyPhen benign (0.012); catalogued as rs751293851, COSV62963298; called by muse, mutect2, varscan2
- PCLO | c.11890C>T p.R3964W | Missense Mutation (SNP) | VAF 128/275 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs756155327, COSV61640264; called by muse, mutect2, varscan2
- PGM5 | c.587C>T p.P196L | Missense Mutation (SNP) | VAF 52/192 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.028); catalogued as COSV101123567; called by muse, varscan2
- RASA4B | c.1651_1653del p.E551del | In Frame Del (DEL) | VAF 185/542 reads (34%) | catalogued as rs764498955; called by pindel, varscan2
- SI | c.2455G>A p.A819T | Missense Mutation (SNP) | VAF 82/205 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.956); catalogued as rs542969966, COSV52286630; called by muse, mutect2, varscan2
- SULT1E1 | c.95C>T p.A32V | Missense Mutation (SNP) | VAF 46/128 reads (36%) | SIFT tolerated (0.11); PolyPhen benign (0.012); catalogued as rs34547148; called by muse, mutect2, varscan2
- TMEM132D | c.530G>A p.R177Q | Missense Mutation (SNP) | VAF 154/349 reads (44%) | SIFT tolerated (0.48); PolyPhen benign (0.02); catalogued as COSV70605025; called by muse, mutect2, varscan2
- TSC2 | c.176G>A p.R59Q | Missense Mutation (SNP) | VAF 275/599 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs1161261925; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ZBTB2 | c.478C>T p.R160W | Missense Mutation (SNP) | VAF 105/243 reads (43%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.793); catalogued as rs576297041; called by muse, mutect2, varscan2
- ANKRD12 | c.5888A>T p.N1963I | Missense Mutation (SNP) | VAF 27/63 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.373); called by muse, mutect2, varscan2
- CCNB3 | c.846G>T p.K282N | Missense Mutation (SNP) | VAF 77/196 reads (39%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.831); called by muse, mutect2, varscan2
- CWC22 | c.1516T>A p.F506I | Missense Mutation (SNP) | VAF 61/226 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CYB5D1 | c.226A>G p.K76E | Missense Mutation (SNP) | VAF 113/308 reads (37%) | SIFT tolerated (0.35); PolyPhen benign (0.13); called by muse, mutect2, varscan2
- ENOX2 | c.1645C>T p.P549S (on ENST00000338144 / NM_001382520.1; = p.P520S on NM_006375.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 35/138 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ETNK2 | c.676G>T p.E226* | Nonsense Mutation (SNP) | VAF 91/407 reads (22%) | called by muse, mutect2, varscan2
- FCGBP | c.5849G>T p.C1950F | Missense Mutation (SNP) | VAF 180/1422 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FHOD3 | c.3789G>T p.Q1263H (on ENST00000359247 / NM_001281739.3; = p.Q1280H on NM_025135.5) | Missense Mutation (SNP) | VAF 94/213 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.817); called by muse, mutect2, varscan2
- GATA6 | c.538_549del p.A180_A183del | In Frame Del (DEL) | VAF 59/166 reads (36%) | called by pindel, varscan2*
- MAMDC4 | c.3154C>A p.L1052I (on ENST00000445819; = p.L973I on NM_206920.3) | Missense Mutation (SNP) | VAF 49/211 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MDM1 | c.1561C>A p.L521I | Missense Mutation (SNP) | VAF 87/218 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- NOD2 | c.2203G>T p.A735S | Missense Mutation (SNP) | VAF 258/515 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- NR3C1 | c.1053dup p.N352* | Frame Shift Ins (INS) | VAF 187/543 reads (34%) | called by mutect2, pindel, varscan2
- OR10A6 | c.245T>G p.L82R | Missense Mutation (SNP) | VAF 59/142 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- OR51G1 | c.439G>T p.G147W | Missense Mutation (SNP) | VAF 33/343 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2
- OTOGL | c.2392T>A p.F798I (on ENST00000547103; = p.F789I on NM_173591.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 47/160 reads (29%) | SIFT tolerated (0.07); PolyPhen benign (0.095); called by muse, mutect2, varscan2
- PCSK4 | c.1976G>A p.C659Y | Missense Mutation (SNP) | VAF 181/383 reads (47%) | SIFT deleterious (0); PolyPhen benign (0.273); called by muse, mutect2, varscan2
- PIK3R1 | c.1314_1358del p.K438_Y452del (on ENST00000521381 / NM_181523.3; = p.K168_Y182del on NM_181504.4) | In Frame Del (DEL) | VAF 22/102 reads (22%) | called by mutect2, pindel
- PRPF3 | c.448A>G p.T150A | Missense Mutation (SNP) | VAF 195/913 reads (21%) | SIFT tolerated (0.06); PolyPhen benign (0.351); called by muse, mutect2, varscan2
- PRPF8 | c.5637_5642del p.P1880_N1881del | In Frame Del (DEL) | VAF 156/435 reads (36%) | called by mutect2, pindel, varscan2
- RAD23A | c.902_904dup p.V301dup | In Frame Ins (INS) | VAF 73/202 reads (36%) | called by mutect2, pindel, varscan2
- RFPL4B | c.487T>C p.C163R | Missense Mutation (SNP) | VAF 142/336 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- RIOK2 | c.1150G>T p.E384* | Nonsense Mutation (SNP) | VAF 109/240 reads (45%) | called by muse, mutect2, varscan2
- SPATA5L1 | c.1085G>A p.R362Q | Missense Mutation (SNP) | VAF 128/360 reads (36%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.745); called by muse, mutect2, varscan2
- TLE1 | c.1900G>T p.G634C | Missense Mutation (SNP) | VAF 60/86 reads (70%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ZFP36 | c.235C>T p.P79S (on ENST00000594442; = p.P73S on NM_003407.5) | Missense Mutation (SNP) | VAF 49/97 reads (51%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ZNHIT2 | c.1022A>G p.Q341R | Missense Mutation (SNP) | VAF 91/188 reads (48%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.778); called by muse, mutect2, varscan2
- ABCA8 | c.4188G>C p.P1396= | Silent (SNP) | VAF 117/293 reads (40%) | catalogued as COSV99286462; called by muse, mutect2, varscan2
- AC011005.1 | c.804G>A p.P268= | Silent (SNP) | VAF 152/375 reads (41%) | catalogued as rs1212440657; called by muse, mutect2, varscan2
- ADGRA1 | c.378G>A p.P126= | Silent (SNP) | VAF 36/77 reads (47%) | catalogued as rs368145789; called by muse, mutect2, varscan2
- DDX25 | c.27C>T p.D9= | Silent (SNP) | VAF 33/68 reads (49%) | catalogued as rs1213979039; called by muse, mutect2, varscan2
- DISC1 | c.1824C>T p.T608= | Silent (SNP) | VAF 109/525 reads (21%) | catalogued as rs140611432; called by muse, mutect2, varscan2
- FBXO21 | c.162T>A p.R54= | Silent (SNP) | VAF 12/323 reads (4%) | called by muse, mutect2
- HCFC1 | c.723G>A p.T241= | Silent (SNP) | VAF 77/207 reads (37%) | catalogued as rs1449522886, COSV100128663; called by muse, mutect2, varscan2
- KRT81 | c.54C>T p.C18= | Silent (SNP) | VAF 285/681 reads (42%) | catalogued as rs770430502, COSV59808881; called by muse, mutect2, varscan2
- MAP3K19 | c.330G>A p.S110= | Silent (SNP) | VAF 62/141 reads (44%) | catalogued as rs1282908518; called by muse, mutect2, varscan2
- PCTP | c.153T>G p.L51= | Silent (SNP) | VAF 44/112 reads (39%) | called by muse, mutect2, varscan2
- SRGAP1 | c.1281G>A p.K427= | Silent (SNP) | VAF 127/324 reads (39%) | catalogued as rs775500354; called by muse, mutect2, varscan2
- XPNPEP2 | c.1758G>T p.L586= | Silent (SNP) | VAF 86/219 reads (39%) | catalogued as COSV100941377; called by muse, mutect2, varscan2
- ZHX2 | c.2010T>C p.T670= | Silent (SNP) | VAF 115/529 reads (22%) | called by muse, mutect2, varscan2
- ACBD5 | chr10:27197296 A>G | 3'Flank (SNP) | VAF 12/94 reads (13%) | called by muse, mutect2
- C2CD6 | c.1581+1512C>T | Intron (SNP) | VAF 29/67 reads (43%) | catalogued as rs895259985; called by muse, mutect2, varscan2
- EIF3E | c.471+1380C>T | Intron (SNP) | VAF 58/91 reads (64%) | called by muse, mutect2, varscan2
- HADH | chr4:107989886 C>T | 5'Flank (SNP) | VAF 151/290 reads (52%) | catalogued as rs756893286; called by muse, mutect2, varscan2
- JAKMIP3 | c.*377C>T | 3'UTR (SNP) | VAF 141/295 reads (48%) | catalogued as rs192051153; called by muse, mutect2, varscan2
- MYL4 | c.163+27G>A | Intron (SNP) | VAF 61/220 reads (28%) | catalogued as rs373073361; called by muse, varscan2
- SH2D3C | c.515+2793G>A | Intron (SNP) | VAF 61/74 reads (82%) | called by muse, mutect2, varscan2
- SPIRE2 | c.289-116G>T | Intron (SNP) | VAF 188/480 reads (39%) | called by muse, mutect2, varscan2
- TPSD1 | chr16:1262701 G>A | 3'Flank (SNP) | VAF 93/183 reads (51%) | catalogued as rs1476332942; called by muse, mutect2, varscan2
- XIAP | chrX:123860151 C>T | 5'Flank (SNP) | VAF 224/540 reads (41%) | called by muse, mutect2, varscan2
